Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A97M, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A97M-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: There is a fragment of skin 8x4 cm in its size with pigmented mass 2x1,5 cm in its size with invasion into fatty tissue.

Microscopic Description: Malignant melanoma (pigmented), in cells of nevus, with ulcerating. Clarks is IV, Breslow is 15 mm.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: More than 4 mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 1.5 x 0 x 2 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Undifferentiated

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Clark's level IV, Breslow is 15 mm

Comments: None

ICD-O-3
Melanoma, malignant NOS
8720/3
Site: Skin of trunk
044.5
4/7/14

Source: NCI Genomic Data Commons file bfaf9b8a-4c14-4c0e-92c4-22c7a0d5bcbf (TCGA-EB-A97M.4EFD3127-7414-49F4-838A-D1050EDDEE31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).